Somatic mutation profile of tumor specimen C3N-00497-01 (aliquot CPT0079100009) from CPTAC case C3N-00497, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 65.0 years (23,739 days).
Specimen C3N-00497-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 727b1dec-39c9-4f3e-a326-531288ae6328.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00497-31 (Blood Derived Normal), aliquot CPT0079140002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f90ac2f-4e5d-496f-a931-2d4cb1332cb5

The open-access MAF lists 331 somatic variants for this specimen: 223 protein-altering or splice-affecting, 75 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 202, Silent 75, Intron 19, Nonsense Mutation 7, Frame Shift Del 6, RNA 5, 3'UTR 5, Splice Region 4, Splice Site 3, 5'UTR 2, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 99/698 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSM2A | c.1087C>T p.Q363* (on ENST00000219054; = p.Q284* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 18/174 reads (10%) | catalogued as COSV54587942; called by muse, varscan2
- ADAMTSL4 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749020217, COSV55001273; ClinVar: uncertain significance; called by muse, mutect2
- AIPL1 | c.150C>A p.D50E | Missense Mutation (SNP) | VAF 83/421 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100006145; called by muse, mutect2, varscan2
- AKAP4 | c.2208C>A p.F736L | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.046); catalogued as COSV100654254; called by muse, mutect2, varscan2
- ANTXRL | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 40/654 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1280653916; called by muse, mutect2
- ASB4 | c.1210A>G p.I404V | Missense Mutation (SNP) | VAF 23/310 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0.02); catalogued as COSV57945398; called by muse, mutect2
- ATP10A | c.2377C>G p.R793G | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.429); catalogued as COSV63512971, COSV63522119; called by muse, mutect2, varscan2
- BRINP2 | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.188); catalogued as COSV64176855; called by muse, mutect2, varscan2
- CCNB3 | c.1907C>A p.S636Y | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs141599713; called by muse, mutect2
- CHST6 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM032870; called by muse, mutect2
- CLEC1B | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs1196973134; called by muse, mutect2, varscan2
- COL11A1 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 66/445 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749430584; called by muse, mutect2, varscan2
- COL22A1 | c.2700G>A p.P900= | Splice Region (SNP) | VAF 14/212 reads (7%) | catalogued as rs1029399664, COSV100278875; called by muse, mutect2
- CPZ | c.392C>A p.P131H (on ENST00000360986 / NM_001014447.3; = p.P120H on NM_003652.3) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.043); catalogued as rs766936569, COSV100249288; called by mutect2, varscan2
- CRNN | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs1186596189; called by muse, mutect2
- CUX1 | c.2749G>A p.V917M | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs782251934; called by muse, mutect2, varscan2
- CYP4X1 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs964059939, COSV100903356; called by muse, mutect2, varscan2
- DZANK1 | c.1892G>T p.G631V (on ENST00000262547 / NM_001099407.1; = p.G438V on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52753551, COSV99361423; called by muse, mutect2, varscan2
- EIF2D | c.862C>T p.L288F | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs782004904; called by muse, mutect2
- EPB41L3 | c.1883G>T p.R628L | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV59443056, COSV59462472; called by muse, mutect2
- ERICH3 | c.4032del p.H1344Qfs*28 | Frame Shift Del (DEL) | VAF 37/298 reads (12%) | catalogued as COSV58606439; called by mutect2, pindel, varscan2
- FAM189B | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs1290641562; called by muse, mutect2
- FAM47C | c.2924del p.G975Vfs*13 | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | catalogued as COSV63725649, COSV63727772; called by mutect2, pindel, varscan2
- FLT4 | c.1696del p.E566Rfs*4 | Frame Shift Del (DEL) | VAF 26/131 reads (20%) | catalogued as COSV56107763; called by mutect2, pindel, varscan2
- FN1 | c.6434C>A p.P2145H (on ENST00000359671 / NM_001365524.2; = p.P2114H on NM_002026.4) | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.967); catalogued as rs144536753, COSV60551155; called by muse, mutect2
- GABRD | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs748341188; called by muse, mutect2, varscan2
- GATA3 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 69/694 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1511800, COSV60517310; called by muse, mutect2
- GJA8 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs782773520, COSV53788628; called by muse, mutect2
- GLIPR1L2 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs533559197; called by muse, mutect2
- GPR6 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.686); catalogued as rs1254780699; called by muse, mutect2, varscan2
- HCN1 | c.2550C>G p.I850M | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.174); catalogued as COSV57532195; called by muse, mutect2, varscan2
- HFM1 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.071); catalogued as rs1195894033; called by muse, mutect2
- ICA1 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55577131; called by muse, mutect2, varscan2
- IGHMBP2 | c.2384C>T p.P795L | Missense Mutation (SNP) | VAF 72/942 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV54822531; called by muse, mutect2
- KAT6B | c.3028C>T p.R1010W | Missense Mutation (SNP) | VAF 30/433 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs142309185; called by muse, mutect2
- KCNH3 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 25/336 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99235049; called by muse, mutect2
- KCNN1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99716433; called by muse, mutect2, varscan2
- KIAA1614 | c.1171C>A p.H391N | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100851143; called by muse, mutect2, varscan2
- KMT2A | c.3908T>A p.L1303Q | Missense Mutation (SNP) | VAF 58/295 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV63283947; called by muse, mutect2, varscan2
- KRT3 | c.707A>T p.Q236L | Missense Mutation (SNP) | VAF 29/314 reads (9%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.993); catalogued as COSV58816933; called by muse, mutect2
- MAP1B | c.5242G>C p.D1748H | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV57104891; called by muse, mutect2
- MAP4K4 | c.2230G>A p.A744T (on ENST00000347699 / NM_001242559.2; = p.A662T on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.91); catalogued as rs199996114, COSV56339293; called by muse, mutect2, varscan2
- MAST4 | c.6305G>C p.S2102T (on ENST00000403625 / NM_001164664.2; = p.S1913T on NM_015183.3) | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as COSV55119365; called by muse, mutect2, varscan2
- MICA | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.067); catalogued as rs753096505; called by muse, mutect2, varscan2
- MKS1 | c.1091C>G p.A364G | Missense Mutation (SNP) | VAF 76/566 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99836631; called by muse, mutect2, varscan2
- MME | c.1282G>C p.V428L | Missense Mutation (SNP) | VAF 71/449 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.495); catalogued as COSV64711379; called by muse, mutect2, varscan2
- NKX6-2 | c.414del p.G139Afs*49 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as COSV100888335; called by mutect2, pindel
- NRG1 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV55149534; called by muse, mutect2
- NRK | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV54597186; called by muse, mutect2
- OLFML1 | c.1109T>G p.M370R | Missense Mutation (SNP) | VAF 22/285 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.284); catalogued as rs759373016, COSV100206536; called by muse, mutect2
- OR5J2 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs142469225, COSV100398880; called by muse, mutect2
- OR6B2 | c.850A>G p.I284V | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs769371813; called by muse, mutect2
- OSCAR | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.216); catalogued as rs1403344107; called by muse, mutect2, varscan2
- PARD3B | c.1949G>T p.W650L | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs1201409192; called by muse, mutect2
- PCARE | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs201617661; called by muse, mutect2, varscan2
- PCDHA3 | c.333C>A p.D111E | Missense Mutation (SNP) | VAF 77/495 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.011); catalogued as COSV100974196, COSV65366760; called by muse, mutect2, varscan2
- PLCE1 | c.1693A>G p.T565A | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs557560167; called by muse, mutect2, varscan2
- PML | c.1658-7G>T | Splice Region (SNP) | VAF 59/407 reads (14%) | catalogued as COSV99167006; called by muse, mutect2, varscan2
- PPFIA4 | c.2566G>A p.V856I (on ENST00000447715; = p.V857I on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs925019525, COSV55322424; called by muse, mutect2
- PTPRC | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV61421960; called by muse, mutect2, varscan2
- QRSL1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV64687451; called by muse, mutect2, varscan2
- RESF1 | c.2599C>T p.H867Y | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100440141; called by muse, mutect2, varscan2
- RHOU | c.734A>T p.N245I | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV64208312; called by muse, varscan2
- RNF111 | c.1544A>G p.H515R | Missense Mutation (SNP) | VAF 25/423 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1202233656; called by muse, mutect2
- SALL3 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs553313475; called by muse, mutect2, varscan2
- SCG5 | c.554C>T p.P185L (on ENST00000300175 / NM_001144757.2; = p.P184L on NM_003020.4) | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV55708081; called by muse, mutect2, varscan2
- SCN1A | c.4900C>A p.L1634M (on ENST00000303395 / NM_001202435.3; = p.L1623M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100319181, COSV57680961; called by muse, mutect2, varscan2
- SF3B4 | c.360C>A p.F120L | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54964519, COSV54965030, COSV54966113; called by muse, mutect2, varscan2
- SHANK1 | c.462C>G p.F154L | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV53243729; called by muse, mutect2
- SLC2A9 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262222259; called by muse, mutect2
- SLC4A4 | c.2442G>A p.K814= (on ENST00000264485 / NM_001098484.3; = p.K770= on NM_003759.4) | Splice Region (SNP) | VAF 24/290 reads (8%) | catalogued as rs749796830, COSV52640833; called by muse, mutect2
- SVIL | c.6449C>G p.A2150G (on ENST00000355867 / NM_021738.3; = p.A1724G on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV63445962; called by muse, mutect2, varscan2
- TEP1 | c.4238C>T p.P1413L | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as rs560280403; called by muse, varscan2
- TMEM132D | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.423); catalogued as rs1022917530, COSV67159866; called by muse, mutect2
- TNFAIP3 | c.1274C>G p.P425R | Missense Mutation (SNP) | VAF 31/375 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as rs748195339, COSV52798121; called by muse, mutect2
- UGT1A9 | c.793G>T p.V265L | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.182); catalogued as COSV60850933; called by muse, varscan2
- USH1C | c.1120T>C p.W374R | Missense Mutation (SNP) | VAF 55/430 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as rs374699745; called by muse, mutect2, varscan2
- UTP20 | c.193G>T p.G65* | Nonsense Mutation (SNP) | VAF 10/146 reads (7%) | catalogued as rs1444527886, COSV55374416; called by muse, mutect2
- ZIC4 | c.908C>A p.P303Q | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV67173786, COSV67173788; called by muse, mutect2, varscan2
- ZIC4 | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs752817308; called by muse, mutect2, varscan2
- ZNF615 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as COSV100943889; called by muse, mutect2
- ZSWIM9 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1192132247; called by muse, mutect2
- AC009093.9 | n.101G>A | Splice Region (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- AC104389.6 | c.88G>T p.G30* | Nonsense Mutation (SNP) | VAF 23/373 reads (6%) | called by muse, mutect2, varscan2
- ACSM2B | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- ADAM2 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ADAMTS2 | c.415T>A p.W139R | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAP1 | c.83-1G>T p.X28_splice | Splice Site (SNP) | VAF 25/123 reads (20%) | called by muse, mutect2, varscan2
- ADGRA2 | c.3760G>A p.E1254K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADGRG4 | c.6914T>A p.M2305K | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ALOX12B | c.1855T>A p.L619M | Missense Mutation (SNP) | VAF 46/352 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANKRD12 | c.4247A>G p.N1416S | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD31 | c.4874A>T p.Q1625L | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- ANKRD7 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ANO4 | c.2425G>T p.A809S (on ENST00000392977 / NM_001286615.2; = p.A774S on NM_178826.4) | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.472); called by muse, mutect2
- ASB7 | c.180A>C p.E60D | Missense Mutation (SNP) | VAF 37/390 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); called by muse, mutect2
- ATP13A3 | c.3706A>G p.T1236A (on ENST00000645319 / NM_001367549.1; = p.T1206A on NM_024524.3) | Missense Mutation (SNP) | VAF 30/460 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2
- ATR | c.4253C>T p.A1418V | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ATR | c.3539C>A p.T1180N | Missense Mutation (SNP) | VAF 57/388 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BAIAP3 | c.1847C>A p.A616D | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.077); called by muse, mutect2
- BCO2 | c.656C>A p.A219D | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BEND3 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.154); called by muse, varscan2
- C17orf75 | c.963C>A p.N321K | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCDC180 | c.2587G>C p.E863Q | Missense Mutation (SNP) | VAF 11/288 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.164); called by muse, mutect2
- CCDC180 | c.3578A>C p.E1193A | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- CCDC39 | c.853G>C p.V285L | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- CCL16 | c.188C>A p.P63Q | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- CEBPZ | c.1190G>C p.R397T | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2
- CEBPZ | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.762); called by muse, mutect2
- CEBPZ | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.215); called by muse, mutect2
- CELF2 | c.494G>A p.R165Q (on ENST00000416382 / NM_001025077.3; = p.R172Q on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- CEP350 | c.2989G>C p.E997Q | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- CHRFAM7A | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- CNGB3 | c.1699G>A p.G567R | Missense Mutation (SNP) | VAF 44/413 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COASY | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- CRNKL1 | c.2425G>A p.D809N | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2
- CYP4F8 | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DAPK1 | c.2524C>G p.L842V | Missense Mutation (SNP) | VAF 21/381 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.101); called by muse, mutect2
- DCHS1 | c.7684T>A p.F2562I | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- DKC1 | c.1300G>T p.A434S | Missense Mutation (SNP) | VAF 109/597 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMRT3 | c.935A>C p.H312P | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- DNAH6 | c.8279A>T p.E2760V | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.098); called by muse, mutect2
- DNMT3L | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- DPPA4 | c.881A>G p.N294S | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- DR1 | c.280T>A p.C94S | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- ENPP3 | c.2320G>C p.V774L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- FAM155A | c.533C>G p.S178W | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- FAM8A1 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, varscan2
- FBN2 | c.3018G>C p.K1006N | Missense Mutation (SNP) | VAF 35/478 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2
- FCGBP | c.4447C>A p.P1483T | Missense Mutation (SNP) | VAF 38/686 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.805); called by muse, mutect2
- FCGR3B | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 45/428 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- FGGY | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOXA2 | c.662C>A p.P221H (on ENST00000377115 / NM_153675.3; = p.P227H on NM_021784.5) | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GDF3 | c.191C>A p.T64N | Missense Mutation (SNP) | VAF 46/303 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GOLGA4 | c.5827G>C p.G1943R | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- GPR137C | c.735G>C p.Q245H | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HCN1 | c.95C>A p.P32Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEMGN | c.1170G>T p.Q390H | Missense Mutation (SNP) | VAF 20/554 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.346); called by muse, mutect2
- HNRNPA2B1 | c.455A>C p.K152T (on ENST00000354667 / NM_031243.3; = p.K140T on NM_002137.4) | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- HSP90B1 | c.89C>A p.T30K | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.248); called by muse, mutect2
- IGHV1OR15-9 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ITPKA | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- KDM6A | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- KDR | c.302A>C p.Y101S | Missense Mutation (SNP) | VAF 56/328 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT2B | c.5663C>G p.P1888R | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KMT2C | c.888A>C p.K296N | Missense Mutation (SNP) | VAF 17/323 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- KRT31 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 14/262 reads (5%) | called by muse, mutect2
- LAMA3 | c.7673A>T p.Y2558F (on ENST00000313654 / NM_198129.4; = p.Y949F on NM_000227.6) | Missense Mutation (SNP) | VAF 28/397 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.207); called by muse, mutect2
- LRP1 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, varscan2
- MAGEB10 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 22/230 reads (10%) | called by muse, mutect2
- MAGED1 | c.320A>T p.Q107L | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAPK8IP2 | c.1123C>G p.P375A | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.118); called by muse, mutect2
- MCHR2 | c.142G>T p.G48W | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAT5 | c.900A>T p.Q300H | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MMS22L | c.1873T>A p.S625T | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- MPST | c.677C>G p.P226R (on ENST00000341116 / NM_001369904.2; = p.P246R on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/397 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- MSH3 | c.2180G>T p.R727L | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MUC22 | c.2954C>A p.T985N | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT tolerated (0.05); called by muse, mutect2, varscan2
- MUC4 | c.15293C>G p.P5098R (on ENST00000463781 / NM_018406.7; = p.P862R on NM_004532.6) | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYH1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- MYO9A | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- NADK2 | c.656G>A p.R219K (on ENST00000381937 / NM_001085411.3; = p.R56K on NM_153013.4) | Missense Mutation (SNP) | VAF 14/345 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- NEXMIF | c.2137G>C p.E713Q | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- NKD1 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPAT | c.948G>T p.L316F | Missense Mutation (SNP) | VAF 48/303 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2L8 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5AN1 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.023); called by muse, mutect2
- OR8D4 | c.826G>C p.V276L | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); called by muse, mutect2
- OSBP | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 32/311 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAK5 | c.1289A>T p.E430V | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- PATL2 | c.929A>T p.K310M | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PIGA | c.853C>G p.R285G | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- PKHD1L1 | c.9965C>A p.T3322K | Missense Mutation (SNP) | VAF 54/235 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PODN | c.548G>C p.R183P (on ENST00000395871; = p.R135P on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.07); called by muse, mutect2
- PPP3CC | c.641T>A p.F214Y | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.166); called by muse, varscan2
- PRDM2 | c.4418A>T p.H1473L | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRPF40A | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PRPF40A | c.427T>G p.S143A | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- PRPF4B | c.2048T>C p.L683P | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PWWP3B | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- RBM3 | c.317-2A>T p.X106_splice | Splice Site (SNP) | VAF 11/157 reads (7%) | called by muse, mutect2
- RRP36 | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2
- RTTN | c.5363C>T p.P1788L | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- RUFY1 | c.476G>C p.G159A | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RYR2 | c.5248G>T p.G1750W | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEZ6L | c.2099A>T p.N700I | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- SLC26A1 | c.181C>A p.R61S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLC39A11 | c.988G>T p.G330* (on ENST00000542342 / NM_001159770.2; = p.G323* on NM_139177.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/225 reads (9%) | called by muse, mutect2
- SLC6A14 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SLC9A7 | c.402G>C p.Q134H | Missense Mutation (SNP) | VAF 35/406 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.793); called by muse, mutect2
- SPEG | c.3307C>T p.P1103S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPIN4 | c.177del p.W59* | Frame Shift Del (DEL) | VAF 21/179 reads (12%) | called by mutect2, varscan2
- STK40 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2
- STRA6 | c.927+1G>T p.X309_splice | Splice Site (SNP) | VAF 92/569 reads (16%) | called by muse, mutect2, varscan2
- SVEP1 | c.10475A>T p.E3492V | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2
- SYN1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TAAR9 | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- TAOK2 | c.2164A>G p.K722E | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.194); called by muse, mutect2
- TCF12 | c.1376G>C p.S459T | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TMEM108 | c.151G>C p.V51L | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- TMX3 | c.26_32del p.A9Gfs*18 | Frame Shift Del (DEL) | VAF 34/296 reads (11%) | called by mutect2, pindel
- TRIM11 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 24/136 reads (18%) | called by muse, mutect2, varscan2
- TRIM11 | c.801G>C p.M267I | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TRMT1L | c.2042T>A p.L681Q | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TSPAN18 | c.698A>C p.E233A | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TTN | c.48185C>A p.T16062K (on ENST00000591111; = p.T8638K on NM_003319.4) | Missense Mutation (SNP) | VAF 24/322 reads (7%) | PolyPhen benign (0.385); called by muse, mutect2
- TTN | c.20998G>T p.V7000L (on ENST00000591111; = p.V6073L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/99 reads (25%) | PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TUBA4A | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 25/331 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.017); called by muse, mutect2
- TXLNB | c.489T>G p.D163E | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TXNDC5 | c.339A>T p.K113N | Missense Mutation (SNP) | VAF 21/287 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.789); called by muse, mutect2
- UBR3 | c.3793_3795dup p.Q1265dup | In Frame Ins (INS) | VAF 35/179 reads (20%) | called by mutect2, pindel
- UNC80 | c.6961G>C p.V2321L | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- VPS37A | c.879A>C p.K293N | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- WDR33 | c.3401A>G p.E1134G | Missense Mutation (SNP) | VAF 19/264 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2
- XIRP1 | c.3235G>A p.G1079S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- YEATS2 | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZFHX4 | c.2860C>A p.L954I | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZFP62 | c.1909A>G p.R637G (on ENST00000502412 / NM_001377944.1; = p.R604G on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF135 | c.1801A>C p.T601P (on ENST00000313434 / NM_001289401.2; = p.T613P on NM_003436.4) | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF227 | c.1375A>G p.T459A | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF572 | c.1052C>G p.T351R | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ZNF804B | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.036); called by muse, mutect2
- ABCG1 | c.450G>A p.R150= | Silent (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- ANO5 | c.1692G>A p.Q564= | Silent (SNP) | VAF 15/233 reads (6%) | called by muse, mutect2
- AP2A1 | c.2475G>T p.V825= | Silent (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- BMI1 | c.612T>C p.Y204= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as rs372205695; called by muse, mutect2, varscan2
- BRF2 | c.1125C>G p.V375= | Silent (SNP) | VAF 30/304 reads (10%) | catalogued as rs1271070066; called by muse, mutect2, varscan2
- BTBD11 | c.702C>G p.A234= | Silent (SNP) | VAF 39/244 reads (16%) | called by muse, mutect2, varscan2
- CDH23 | c.5685C>A p.R1895= | Silent (SNP) | VAF 14/169 reads (8%) | catalogued as COSV56479798; called by muse, mutect2
- CEP162 | c.3117G>A p.Q1039= | Silent (SNP) | VAF 33/266 reads (12%) | called by muse, mutect2, varscan2
- CERKL | c.1632T>A p.L544= (on ENST00000339098 / NM_001030311.2; = p.L518= on NM_201548.5) | Silent (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2
- CHRM5 | c.768T>C p.C256= | Silent (SNP) | VAF 32/183 reads (17%) | called by muse, mutect2, varscan2
- COL24A1 | c.2445T>C p.F815= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- COL27A1 | c.690C>G p.T230= | Silent (SNP) | VAF 16/204 reads (8%) | called by muse, mutect2
- CPED1 | c.1497G>A p.L499= | Silent (SNP) | VAF 11/182 reads (6%) | catalogued as COSV60001334; called by muse, mutect2
- CUX2 | c.3294G>A p.K1098= | Silent (SNP) | VAF 11/177 reads (6%) | called by muse, mutect2
- CXCR3 | c.87T>C p.Y29= | Silent (SNP) | VAF 40/252 reads (16%) | catalogued as rs1446879115; called by muse, mutect2, varscan2
- CYP3A4 | c.514T>C p.L172= | Silent (SNP) | VAF 19/302 reads (6%) | called by muse, mutect2
- DNAH17 | c.11124C>T p.D3708= | Silent (SNP) | VAF 26/293 reads (9%) | catalogued as rs763823748, COSV67759144, COSV67760318; called by muse, mutect2
- DOP1A | c.6495A>C p.A2165= | Silent (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- EGFL7 | c.189C>T p.S63= | Silent (SNP) | VAF 10/145 reads (7%) | called by muse, mutect2
- ELFN2 | c.807A>G p.P269= | Silent (SNP) | VAF 22/157 reads (14%) | catalogued as rs1361595547; called by muse, mutect2, varscan2
- ERICH3 | c.1060C>T p.L354= | Silent (SNP) | VAF 22/156 reads (14%) | catalogued as rs1304589314, COSV58606906, COSV99044796; called by mutect2, varscan2
- FAM71E2 | c.1887G>A p.K629= | Silent (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- FBXL7 | c.1272C>T p.A424= | Silent (SNP) | VAF 20/384 reads (5%) | called by muse, mutect2
- FBXW9 | c.300C>T p.L100= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as rs752062927; called by muse, mutect2, varscan2
- FILIP1L | c.2820C>T p.G940= (on ENST00000354552 / NM_182909.3; = p.G700= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- FLG | c.2535G>A p.P845= | Silent (SNP) | VAF 70/536 reads (13%) | catalogued as rs148002225; called by muse, mutect2, varscan2
- GRIN2A | c.2415C>T p.N805= | Silent (SNP) | VAF 28/342 reads (8%) | catalogued as rs777235967, COSV58033170; ClinVar: uncertain significance; called by muse, mutect2
- GRIN2C | c.2715C>A p.T905= | Silent (SNP) | VAF 52/285 reads (18%) | called by muse, mutect2, varscan2
- HIVEP2 | c.5070G>T p.T1690= | Silent (SNP) | VAF 54/368 reads (15%) | catalogued as rs371213412; called by muse, mutect2, varscan2
- INPP5D | c.1215C>A p.T405= (on ENST00000445964 / NM_001017915.3; = p.T404= on NM_005541.5) | Silent (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- ITGA11 | c.1338C>T p.P446= | Silent (SNP) | VAF 23/377 reads (6%) | called by muse, mutect2
- KCNK3 | c.78C>T p.F26= | Silent (SNP) | VAF 58/235 reads (25%) | called by muse, mutect2, varscan2
- KIAA1755 | c.1194C>T p.S398= | Silent (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- LGALS1 | c.126G>C p.L42= | Silent (SNP) | VAF 42/292 reads (14%) | catalogued as rs749755389; called by muse, varscan2
- LRRK1 | c.90G>A p.T30= | Silent (SNP) | VAF 20/230 reads (9%) | catalogued as rs779249857; called by muse, mutect2
- MCEE | c.30G>A p.A10= | Silent (SNP) | VAF 38/574 reads (7%) | called by muse, mutect2
- MTNR1A | c.603C>T p.I201= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as rs1238760758, COSV56156933; called by muse, mutect2
- MUC17 | c.5691T>C p.P1897= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, varscan2
- MUC22 | c.2955C>A p.T985= | Silent (SNP) | VAF 49/377 reads (13%) | called by muse, mutect2, varscan2
- MYH2 | c.2445G>A p.E815= | Silent (SNP) | VAF 35/264 reads (13%) | called by muse, mutect2, varscan2
- NHSL1 | c.3348A>G p.P1116= | Silent (SNP) | VAF 38/208 reads (18%) | catalogued as rs1320501675; called by muse, mutect2, varscan2
- OR2AG1 | c.159C>T p.A53= | Silent (SNP) | VAF 12/175 reads (7%) | catalogued as COSV100264918; called by muse, mutect2
- OR2T1 | c.480C>A p.P160= | Silent (SNP) | VAF 33/184 reads (18%) | catalogued as COSV63542072; called by muse, mutect2, varscan2
- OR4C12 | c.303A>T p.A101= | Silent (SNP) | VAF 26/172 reads (15%) | called by muse, mutect2, varscan2
- OR56A4 | c.147G>A p.R49= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs772997785, COSV58109513; called by muse, mutect2, varscan2
- PCARE | c.1560C>T p.D520= | Silent (SNP) | VAF 40/751 reads (5%) | catalogued as rs367995216, COSV59057518; called by muse, mutect2
- PCDHB16 | c.384C>T p.D128= | Silent (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- PDE2A | c.2631G>A p.L877= | Silent (SNP) | VAF 15/230 reads (7%) | called by muse, mutect2
- PENK | c.15G>C p.L5= | Silent (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2
- PIK3C2G | c.4413C>G p.V1471= (on ENST00000676171; = p.V1430= on NM_004570.5) | Silent (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- PIK3CD | c.2793A>T p.P931= | Silent (SNP) | VAF 55/387 reads (14%) | called by muse, mutect2, varscan2
- PLA2R1 | c.3114T>C p.P1038= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as rs1396858813, COSV51778646; called by muse, mutect2
- POU5F1B | c.969C>T p.G323= | Silent (SNP) | VAF 32/595 reads (5%) | called by muse, mutect2
- PPP1R26 | c.66A>G p.P22= | Silent (SNP) | VAF 24/172 reads (14%) | called by muse, mutect2, varscan2
- ROR2 | c.112C>T p.L38= | Silent (SNP) | VAF 57/505 reads (11%) | called by muse, mutect2, varscan2
- RTL8B | c.132C>T p.I44= | Silent (SNP) | VAF 45/275 reads (16%) | catalogued as COSV101195554; called by muse, mutect2, varscan2
- SLC2A4 | c.960C>G p.G320= | Silent (SNP) | VAF 43/527 reads (8%) | called by muse, mutect2
- SLC39A11 | c.987G>T p.L329= (on ENST00000542342 / NM_001159770.2; = p.L322= on NM_139177.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/227 reads (10%) | catalogued as COSV99723498; called by muse, mutect2
- SLITRK4 | c.963C>A p.L321= | Silent (SNP) | VAF 26/278 reads (9%) | called by muse, mutect2
- SLITRK5 | c.894G>C p.T298= | Silent (SNP) | VAF 11/186 reads (6%) | called by muse, mutect2
- SLTM | c.3099A>C p.R1033= | Silent (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2
- SPATA31D1 | c.4317G>T p.G1439= | Silent (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- TACC2 | c.7947A>G p.L2649= (on ENST00000334433; = p.L727= on NM_006997.4) | Silent (SNP) | VAF 37/299 reads (12%) | catalogued as rs779388403; called by muse, mutect2, varscan2
- TBC1D1 | c.2727G>A p.A909= | Silent (SNP) | VAF 25/401 reads (6%) | catalogued as rs576791254, COSV54718078; called by muse, mutect2
- TBX20 | c.693G>A p.V231= | Silent (SNP) | VAF 28/233 reads (12%) | catalogued as COSV68785286; called by muse, mutect2, varscan2
- TCF23 | c.93C>T p.D31= | Silent (SNP) | VAF 68/354 reads (19%) | catalogued as COSV99940341; called by muse, mutect2, varscan2
- TENM3 | c.120C>T p.S40= | Silent (SNP) | VAF 36/472 reads (8%) | catalogued as COSV69313003; called by muse, mutect2
- TMEM181 | c.156G>A p.T52= | Silent (SNP) | VAF 14/165 reads (8%) | catalogued as rs1001169537; called by muse, mutect2
- TMEM52B | c.180G>C p.L60= (on ENST00000381923 / NM_001079815.1; = p.L40= on NM_153022.4) | Silent (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- USH2A | c.6456T>A p.T2152= | Silent (SNP) | VAF 37/358 reads (10%) | called by muse, mutect2
- WIZ | c.423G>T p.R141= | Silent (SNP) | VAF 33/189 reads (17%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.6423G>A p.T2141= | Silent (SNP) | VAF 84/427 reads (20%) | catalogued as rs142448052; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF462 | c.1248G>C p.L416= | Silent (SNP) | VAF 26/274 reads (9%) | called by muse, mutect2
- ZNF543 | c.810C>T p.L270= | Silent (SNP) | VAF 42/367 reads (11%) | called by muse, mutect2, varscan2
- ZNF592 | c.2571C>T p.P857= | Silent (SNP) | VAF 37/279 reads (13%) | catalogued as rs910585869; called by muse, mutect2, varscan2
- AC005400.1 | n.179-334C>A | Intron (SNP) | VAF 20/220 reads (9%) | catalogued as rs770455133; called by muse, mutect2
- AC241952.1 | n.813A>T | RNA (SNP) | VAF 39/335 reads (12%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852089 G>A | 3'Flank (SNP) | VAF 27/412 reads (7%) | called by muse, mutect2
- ALDOA | c.*4G>A | 3'UTR (SNP) | VAF 39/243 reads (16%) | called by muse, mutect2, varscan2
- AMACR | c.*719G>T | 3'UTR (SNP) | VAF 45/155 reads (29%) | called by muse, mutect2, varscan2
- ATP13A1 | c.396+91C>T | Intron (SNP) | VAF 45/307 reads (15%) | catalogued as rs1275262812; called by muse, mutect2, varscan2
- BMPER | c.*33G>A | 3'UTR (SNP) | VAF 9/207 reads (4%) | called by muse, mutect2
- CCL3L3 | c.76+181C>T | Intron (SNP) | VAF 42/1219 reads (3%) | called by muse, mutect2
- COPZ2 | c.547-22C>G | Intron (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- DENND10P1 | n.1141C>T | RNA (SNP) | VAF 55/298 reads (18%) | called by muse, mutect2, varscan2
- EGFR | c.2469+21C>T | Intron (SNP) | VAF 45/291 reads (15%) | catalogued as rs201720393; called by muse, mutect2, varscan2
- FAM183BP | n.1075G>T | RNA (SNP) | VAF 51/409 reads (12%) | called by muse, mutect2, varscan2
- FLT4 | c.2648-68A>T | Intron (SNP) | VAF 16/94 reads (17%) | called by mutect2, varscan2
- GCGR | c.-43G>A | 5'UTR (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- GTF2IRD2P1 | n.2243C>T | RNA (SNP) | VAF 33/734 reads (4%) | called by muse, mutect2
- H3-2 | c.*52G>A | 3'UTR (SNP) | VAF 34/760 reads (4%) | called by muse, mutect2
- HTR2C | c.-80+17030A>T | Intron (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- IFT172 | c.336+23G>A | Intron (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- IL2RG | c.854+26dup | Intron (INS) | VAF 29/162 reads (18%) | called by mutect2, pindel, varscan2
- IWS1 | c.-204G>A | 5'UTR (SNP) | VAF 13/165 reads (8%) | called by muse, mutect2
- LMNA | c.*745G>A | 3'UTR (SNP) | VAF 9/44 reads (20%) | called by muse, varscan2
- MCCC2 | c.1073-31G>C | Intron (SNP) | VAF 48/351 reads (14%) | catalogued as rs1354954258; called by muse, mutect2, varscan2
- PACS1 | c.978+764G>A | Intron (SNP) | VAF 18/162 reads (11%) | called by muse, varscan2
- PITX2 | c.185-899C>A | Intron (SNP) | VAF 36/344 reads (10%) | called by muse, mutect2
- POM121L4P | n.930C>T | RNA (SNP) | VAF 42/682 reads (6%) | catalogued as rs753458299; called by muse, mutect2
- PRRC2B | c.5759-354A>T | Intron (SNP) | VAF 14/230 reads (6%) | called by muse, mutect2
- REV3L | c.9043-657T>C | Intron (SNP) | VAF 15/94 reads (16%) | catalogued as rs1381955522; called by muse, mutect2, varscan2
- SCP2D1 | chr20:18809911 C>A | 5'Flank (SNP) | VAF 54/337 reads (16%) | called by muse, mutect2, varscan2
- SGCE | c.1486+941del | Intron (DEL) | VAF 15/155 reads (10%) | called by mutect2, pindel
- SPAG6 | c.121+57C>A | Intron (SNP) | VAF 18/200 reads (9%) | catalogued as COSV100510352; called by muse, mutect2
- WNK1 | c.2140-2458C>G | Intron (SNP) | VAF 74/224 reads (33%) | called by muse, mutect2, varscan2
- ZNF497 | c.-111-544G>C | Intron (SNP) | VAF 23/146 reads (16%) | called by muse, mutect2, varscan2
- ZNF606 | c.-52+57G>A | Intron (SNP) | VAF 30/200 reads (15%) | called by mutect2, varscan2
